Somatic mutation profile of tumor specimen TCGA-DE-A0Y2-01A (aliquot TCGA-DE-A0Y2-01A-11D-A10S-08) from TCGA case TCGA-DE-A0Y2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.7 years (11,227 days).
Specimen TCGA-DE-A0Y2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e2cd6e8-34e2-4159-8a16-a2ea1370b8e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A0Y2-10A (Blood Derived Normal), aliquot TCGA-DE-A0Y2-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eaef61e-20e6-4986-bbc1-c39fb9634d9a

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 8, Silent 7, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FFAR4 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV65179233; called by muse, mutect2, varscan2
- JMJD1C | c.4402C>T p.Q1468* | Nonsense Mutation (SNP) | VAF 79/181 reads (44%) | catalogued as COSV59516330; called by muse, mutect2, varscan2
- LPAR6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57313450; called by muse, mutect2, varscan2
- LRATD1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.209); catalogued as COSV54473322; called by muse, mutect2, varscan2
- OVGP1 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63858891; called by muse, mutect2, varscan2
- PLEC | c.1243del p.Q415Sfs*45 (on ENST00000322810 / NM_201380.4; = p.Q305Sfs*45 on NM_000445.5) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as CM050308; called by mutect2, pindel, varscan2
- POMT2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55072019; called by muse, varscan2
- RIOK2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV51613447; called by muse, mutect2, varscan2
- TDRD7 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1479414960, COSV62430043; called by muse, mutect2, varscan2
- VAPA | c.547C>T p.Q183* (on ENST00000400000 / NM_194434.3; = p.Q228* on NM_003574.6) | Nonsense Mutation (SNP) | VAF 49/91 reads (54%) | catalogued as COSV61298395; called by muse, mutect2, varscan2
- ZFAND5 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | catalogued as COSV52988291, COSV99428532; called by muse, mutect2, varscan2
- ZNF564 | c.1232A>T p.H411L | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59435553; called by muse, mutect2
- RAI1 | c.5383G>T p.E1795* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- ATP10A | c.309G>A p.V103= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV63519526; called by muse, mutect2, varscan2
- DNAAF2 | c.396G>A p.A132= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53568729, COSV53572344; called by mutect2, varscan2
- FBH1 | c.678C>T p.F226= (on ENST00000362091 / NM_178150.3; = p.F277= on NM_032807.4) | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV62983173; called by muse, mutect2
- LMAN2L | c.174G>A p.S58= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs1394736467, COSV53841621; called by muse, mutect2, varscan2
- MOS | c.63G>A p.A21= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs374238566; called by muse, mutect2, varscan2
- POMT2 | c.258G>A p.E86= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs956763108, COSV55072031; called by muse, varscan2
- TGDS | c.51G>A p.A17= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs1439279581, COSV54301296; called by muse, mutect2, varscan2
